Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A9SG, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A9SG-01A (Primary Tumor).

[page 1 of 6]
Collected:
Ordered by:

DIAGNOSIS:

RADICAL CYSTECTOMY, BILATERAL PELVIC LYMPH NODE DISSECTION WITH ORTHOTOPIC NEOBLADDER:

RIGHT DISTAL URETER (A):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT DISTAL URETER (B):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

APICAL URETHRAL MARGIN (C):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETHRAL AND PERIURETHRAL TISSUE
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

BLADDER / PROSTATE (D):

BLADDER:

- INVASIVE POORLY DIFFERENTIATED UROTHELIAL CARCINOMA (5.0 X 2.0 X 1.0 CM), GRADES 3 & 4/4, INVOLVING SUPERFICIAL MUSCULARIS PROPRIA OF LEFT LATERAL WALL
- FOCAL UROTHELIAL CARCINOMA IN SITU (FLAT LESION) PRESENT ADJACENT TO INVASIVE CARCINOMA
- LEFT URETEROVESICAL JUNCTION, MODERATE TO SEVERE UROTHELIAL DYSPLASIA
- NO LYMPHOVASCULAR SPACE INVASION IDENTIFIED
- RESECTION MARGINS, FREE OF UROTHELIAL DYSPLASIA AND MALIGNANCY
- REACTIVE ATYPIA ASSOCIATED WITH CYSTITIS GLANDULARIS AND CYSTITIS CYSTICA OF NON-NEOPLASTIC URINARY BLADDER MUCOSA

PROSTATE:

- FOCAL ADENOMATOUS HYPERPLASIA WITH NO HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN) OR MALIGNANCY IDENTIFIED
- CHRONIC NONSPECIFIC INFLAMMATION
- PROSTATIC URETHRA, FREE OF UROTHELIAL DYSPLASIA AND MALIGNANCY
- SEMINAL VESICLES AND VASA DEFERENTIA, NO SIGNIFICANT HISTOPATHOLOGIC CHANGE

LEFT PARA AORTIC LYMPH NODES (E):

- NO TUMOR IDENTIFIED IN NINE LYMPH NODES EXAMINED (0/9)

RIGHT PARACAVAL LYMPH NODES (F):

- NO TUMOR IDENTIFIED IN TEN LYMPH NODES EXAMINED (0/10)

RIGHT COMMON ILIAC LYMPH NODES (G):

- NO TUMOR IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

LEFT COMMON ILIAC LYMPH NODES (H):

- NO TUMOR IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

ICD O-3
Carcinoma, urothelial NOS
812013
Site Bladder NOS C67.9
path Bladder, lateral wall C67.2
JW 3/26/14

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

RIGHT EXTERNAL ILIAC LYMPH NODES (I):

- NO TUMOR IDENTIFIED IN 11 LYMPH NODES EXAMINED (0/11)

RIGHT LYMPH NODE OF CLOQUET (J):

- NO LYMPHOID TISSUE OR TUMOR IDENTIFIED (0/0)

RIGHT OBTURATOR / HYPOGASTRIC LYMPH NODES (K):

- NO TUMOR IDENTIFIED IN 21 LYMPH NODES EXAMINED (0/21)

LEFT EXTERNAL ILIAC LYMPH NODES (L):

- NO TUMOR IDENTIFIED IN 13 LYMPH NODES EXAMINED (0/13)

LEFT LYMPH NODE OF CLOQUET (M):

- NO TUMOR IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

LEFT OBTURATOR / HYPOGASTRIC LYMPH NODES (N):

- NO TUMOR IDENTIFIED IN 22 LYMPH NODES EXAMINED (0/22)

RIGHT PRESACRAL LYMPH NODES (O):

- NO TUMOR IDENTIFIED IN FIVE LYMPH NODES EXAMINED (0/5)

PRESACRAL LYMPH NODES (P):

- NO TUMOR IDENTIFIED IN FIVE LYMPH NODES EXAMINED (0/5)

LEFT PRESACRAL LYMPH NODES (Q):

- NO TUMOR IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

LEFT PROXIMAL URETER (R):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT PROXIMAL URETER (S):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LYMPH NODE SUMMARY: NO TUMOR IDENTIFIED IN 111 LYMPH NODES
EXAMINED (0/111)

PATHOLOGIC TNM STAGE: pT2aN0MX

Electronically signed by

COMMENT:

Representative sections of invasive carcinoma are submitted for p53 assay by immunohistology, results of which will be issued in an addendum.

SPECIMEN SOURCE:

- A: "Right distal ureter"
- B: "Left distal ureter"
- C: "Apical urethral margin f/s"
- D: "Bladder/prostate"
- E: "Left para aortic lymph node"
- F: "Right para caval lymph node"
- G: "Right common iliac lymph node"
- H: "Left common iliac lymph node"

[page 3 of 6]
Collected:

Offered by:

Location:

I: "right external iliac lymph node"
J: "Right lymph node of cloquet"
K: "Right obturator / hypogastric lymph node"
L: "Left external iliac lymph node"
M: "Left lymph node of cloquet"
N: "Left obturator / hypogastric lymph node"
O: "Right pre-sciatic lymph node"
P: "Pre sacral lymph node"
Q: "Left pre-sciatic lymph node"
R: "Left proximal ureter"
S: "Right proximal ureter"

CLINICAL INFORMATION:

Pre-Op Dx: TCC of bladder

Post-Op Dx: Same as pre-op

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labelled "Right distal ureter". It consists of a segment of ureter measuring 0.5 cm in length and 0.3 cm in diameter. The specimen is entirely submitted for frozen section in cassette AFS.

B: The specimen is received fresh from the O.R. and labelled "Left distal ureter". It consists of a segment of ureter measuring 0.5 cm in length and 0.3 cm in diameter. The specimen is entirely submitted for frozen section in cassette BFS.

CFS: The specimen is received fresh from the O.R. and labelled "Apical urethral margin f/s". It consists of two pieces of tan soft tissue measuring 1.2 x 0.7 x 0.4 cm and 1.2 x 0.4 x 0.3 cm, respectively. The specimen is entirely submitted for frozen section in cassette CFS.

D: The specimen is received fresh from the O.R. and labelled "Bladder/prostate". It consists of a bladder with attached prostate and peritoneum. Overall, the specimen measures 29.5 x 12.5 x 3 cm. The peritoneum measures 23 x 12 x < 0.1 cm. The peritoneum is smooth and glistening. The prostate and the left side of the urinary bladder are inked black. The prostate and bladder are then opened along the anterior prostatic urethra and the bladder wall. The urinary bladder measures 6.5 x 5.5 x 3 cm. The opened bladder reveals an exophytic polypoid tumor in the left lateral wall. The tumor measures 5 x 2 x 1 cm. The base which is attached to the urinary bladder wall measures 1.5 x 1 cm. The tumor is 1.5 cm superior to the left ureterovesical junction. The tumor invades the urinary bladder wall superficially. No involvement of perivesical fat is seen. The right and left ureterovesical junctions are identified. Both ureters are normal and not obstructed. The right ureter measures 3.5 cm in length and 0.5 cm in circumference. The left ureter measures 4 cm in length and 0.6 cm in circumference. The mucosa of non-neoplastic urinary bladder and bilateral ureters are unremarkable. The prostate measures 5 x 4 x 3 cm. The urethra measures 3.5 cm in length and 3 cm in circumference. The verumontanum measures 1.2 x 0.7 x 0.4 cm and is unremarkable grossly. The prostate is cross sectioned perpendicular to the prostatic urethra. Cross sections show multiple nodular lesions in the central zone, consistent with benign prostatic hyperplasia. Representative sections are submitted in 25 cassettes.

E: The specimen is received in formalin and labelled "Left para aortic lymph node". It consists of two pieces of tan soft tissue measuring 3 x 1 x 0.4 cm in aggregate. The specimen is entirely submitted in three cassettes.

F: The specimen is received in formalin and labelled "Right para caval lymph node". It consists of a piece of tan soft tissue measuring 3 x 1.5 x 0.6 cm. The

[page 4 of 6]
Collected:	
Ordered by:	
Location:	

specimen is entirely submitted in three cassettes.

G: The specimen is received in formalin and labelled "Right common iliac lymph node". It consists of multiple tan soft tissue fragments measuring 4 x 2 x 0.6 cm in aggregate. the specimen is entirely submitted in five cassettes.

H: The specimen is received in formalin and labelled "Left common iliac lymph node". It consists of multiple tan soft tissue fragments measuring 2 x 1 x 0.4 cm in aggregate. The specimen is entirely submitted in two cassettes.

I: The specimen is received in formalin and labelled "Right external iliac lymph node". It consists of multiple tan-yellow fibroadipose tissue fragments measuring 5 x 2.5 x 1 cm in aggregate. The specimen is entirely submitted in six cassettes.

J: The specimen is received in formalin and labelled "Right lymph node of cloquet". It consists of two pieces of tan soft tissue measuring 0.8 x 0.4 x 0.2 cm in aggregate. The specimen is entirely submitted in one cassette.

K: The specimen is received in formalin and labelled "Right obturator / hypogastric lymph node". It consists of multiple tan-yellow soft tissue fragments measuring 5 x 2 x 1 cm in aggregate. The specimen is entirely submitted in six cassettes.

L: The specimen is received in formalin and labelled "Left external iliac lymph node". It consists of multiple tan-yellow soft tissue fragments measuring 4.5 x 2 x 0.6 cm in aggregate. The specimen is entirely submitted in five cassettes.

M: The specimen is received in formalin and labelled "Left lymph node of cloquet". It consists of a piece of tan soft tissue measuring 0.8 x 0.6 x 0.2 cm. The specimen is entirely submitted in one cassette.

N: The specimen is received in formalin and labelled "Left obturator / hypogastric lymph node". It consists of multiple tan-yellow fibroadipose tissue fragments measuring 6 x 2 x 1 cm in aggregate. The specimen is entirely submitted in six cassettes.

O: The specimen is received in formalin and labelled "Right presciatic lymph node". It consists of multiple tan-yellow soft tissue fragments measuring 1.5 x 1 x 0.2 cm in aggregate. The specimen is entirely submitted in one cassette.

P: The specimen is received in formalin and labelled "Pre sacral lymph node". It consists of multiple tan-yellow fibroadipose tissue fragments measuring 3 x 2 x 0.4 cm in aggregate. The specimen is entirely submitted in two cassettes.

Q: The specimen is received in formalin and labelled "Left presciatic lymph node". It consists of multiple tan-yellow soft adipose tissue fragments measuring 1.5 x 0.8 x 0.2 cm in aggregate. The specimen is entirely submitted in one cassette.

R: The specimen is received in formalin and labelled "Left proximal ureter". It consists of a segment of ureter measuring 0.5 cm in length and 0.4 cm in diameter. The specimen is entirely submitted in one cassette.

S: The specimen is received in formalin and labelled "Right proximal ureter". It consists of a segment of ureter measuring 0.5 cm in length and 0.4 cm in diameter. The specimen is entirely submitted in one cassette.

SECTIONS:

AFS:	frozen section, right distal ureter
BFS:	frozen section, left distal ureter
CFS:	frozen section, apical urethral margin

[page 5 of 6]
Collected
Ordered by

D1: anterior urinary bladder wall
D2: right lateral urinary bladder wall
D3: right ureterovesical junction
D4: dome
D5: left lateral urinary bladder wall
D6: left ureterovesical junction
D7: posterior urinary bladder wall
D8: trigone to prostatic urethra
D9-13: tumor with radial margin
D14: right perivesical soft tissue for lymph node
D15: left perivesical soft tissue and lymph node
D16: right distal prostate
D17: left distal prostate
D18: right mid anterior prostate
D19: right mid posterior prostate
D20: left mid anterior prostate
D21: left mid posterior prostate
D22: right proximal anterior prostate
D23: right proximal posterior prostate
D24: left proximal anterior prostate
D25: left proximal posterior prostate
E1-3: left para-aortic lymph node - all embedded
F1-3: right paracaval lymph node - all embedded
G1-5: right common iliac lymph node - all embedded
H1,2: left common iliac lymph node - all embedded
I1-6: right external iliac lymph node - all embedded
J: right lymph node of Cloquet - all embedded
K1-6: right obturator / hypogastric lymph node - all embedded
L1-5: left external iliac lymph node - all embedded
M: left lymph node of Cloquet - all embedded
N1-6: left obturator / hypogastric lymph node - all embedded
O: right presciatic lymph node - all embedded
P1,2: presacral lymph node - all embedded
Q: left presciatic lymph node - all embedded
R: left proximal ureter - all embedded
S: right proximal ureter - all embedded

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right distal ureter:
- no high grade atypia or tumor identified

BFS: Left distal ureter:
- no high grade atypia or tumor identified

CFS: Apical urethral margin:
- no high grade atypia or tumor identified

MICROSCOPIC EXAMINATION:

A-B: See final microscopic-diagnosis.

C: Sections of the apical urethral margin show benign urethral and periurethral tissue with chronic inflammation. A separate detached fragment (floater) of tumor is seen in the lumen in the permanent sections only. It is not associated with the urethral mucosa or stroma.

[page 6 of 6]
Temporary Copy

Collected

Ordered by

D: Sections of the bladder show poorly differentiated urothelial carcinoma (D9,10,12), involving the left lateral wall and invading the superficial muscularis propria (D10,12). Individual tumor cells range from moderate to markedly pleomorphic, corresponding to grades 3 & 4/4. Urothelial carcinoma in situ (flat lesion) is seen in the adjacent mucosa (D10,12,13) with a focus of moderate to severe dysplasia involving the left UVJ. No perineural or lymphovascular invasion is identified. Sections of the non-neoplastic bladder mucosa show multifocal chronic inflammation with cystitis cystica and glandularis. Resection margins are free of urothelial dysplasia and malignancy. No lymph nodes or tumor is seen in the perivesical fat. Sections that include the distal prostatic urethra (D16) show a detached fragment of urothelial carcinoma in the urethral lumen, consistent with contaminant, similar to that described in specimen C above.

E-S: See final microscopic-diagnosis.

Source: NCI Genomic Data Commons file 9d936385-3fdc-4ce5-891a-f7b9b4224769 (TCGA-XF-A9SG.FD5739DB-DC2E-4291-ADBD-12C12EFCACCF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).